Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A299, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A299-01A (Primary Tumor).

OC#: TSS #

Procurement Date: Laterality: NA

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Skin

Tumor size: 2.5 x 2 x 1 cm

Tumor features: None specified

Satellite nodules: Not specified

Histologic type: Nodular Melanoma

Histologic grade: Moderately differentiated

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Clark level III invasion

1CD-0-3

Melanoma, nodular 8721/3

Site: SKIN, NOS C44.9

hr
5/23/11

Source: NCI Genomic Data Commons file 3bd2a1d8-ee30-408b-b673-8c61704684ec (TCGA-EB-A299.A5C7EB35-65E4-4544-80BA-6F20860F0571.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).